Somatic mutation profile of tumor specimen C3L-01470-01 (aliquot CPT0085580009) from CPTAC case C3L-01470, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 51.0 years (18,613 days).
Specimen C3L-01470-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80d67734-8ed2-4f17-b101-b386039c0606.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01470-31 (Blood Derived Normal), aliquot CPT0086570002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0beb1a16-bef7-4d41-9a65-2b8e90bc5966

The open-access MAF lists 56 somatic variants for this specimen: 36 protein-altering or splice-affecting, 8 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 8, Intron 7, Frame Shift Del 3, RNA 2, 3'UTR 2, Nonsense Mutation 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG4 | c.749G>A p.G250D | Missense Mutation (SNP) | VAF 56/342 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56642722; called by muse, mutect2, varscan2
- C2CD3 | c.5750C>T p.T1917M | Missense Mutation (SNP) | VAF 130/822 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs111412489, COSV58095965; called by muse, mutect2, varscan2
- CACNA1A | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs773461333, COSV64215356; ClinVar: uncertain significance; called by muse, mutect2
- CSAD | c.88G>A p.D30N (on ENST00000444623 / NM_001244705.2; = p.D57N on NM_015989.5) | Missense Mutation (SNP) | VAF 77/286 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs756102286; called by muse, mutect2, varscan2
- EYS | c.1635A>T p.E545D | Missense Mutation (SNP) | VAF 85/285 reads (30%) | SIFT tolerated (0.78); PolyPhen benign (0.017); catalogued as COSV60991316; called by muse, mutect2, varscan2
- FRMPD1 | c.1375G>A p.V459I | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.401); catalogued as rs774561681, COSV100899266; called by muse, mutect2, varscan2
- KRT13 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 70/272 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.05); catalogued as COSV99877453; called by muse, mutect2, varscan2
- LPL | c.686A>G p.H229R | Missense Mutation (SNP) | VAF 190/614 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1287351470, CM155098; called by muse, varscan2
- NDUFS7 | c.256C>G p.L86V | Missense Mutation (SNP) | VAF 158/564 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.725); catalogued as rs758518373; called by muse, mutect2, varscan2
- OTOG | c.5284C>T p.P1762S | Missense Mutation (SNP) | VAF 88/221 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs1486479305; called by muse, mutect2, varscan2
- PIANP | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 64/219 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.487); catalogued as rs868149476, COSV57707498; called by muse, mutect2, varscan2
- PLEKHO1 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 95/309 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs782805199; called by muse, mutect2, varscan2
- TAF1L | c.1535G>A p.R512Q | Missense Mutation (SNP) | VAF 34/294 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs962298164; called by muse, mutect2, varscan2
- TNS2 | c.448G>A p.D150N (on ENST00000314250 / NM_170754.4; = p.D160N on NM_015319.2) | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.175); catalogued as rs997442621, COSV58576047; called by muse, mutect2, varscan2
- AFF2 | c.3573A>G p.Q1191= | Splice Region (SNP) | VAF 42/58 reads (72%) | called by muse, mutect2, varscan2
- AFMID | c.34A>G p.K12E | Missense Mutation (SNP) | VAF 81/306 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMOTL2 | c.491A>T p.Q164L | Missense Mutation (SNP) | VAF 103/337 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- CD44 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 75/470 reads (16%) | called by muse, mutect2, varscan2
- DOCK4 | c.652C>A p.L218M | Missense Mutation (SNP) | VAF 87/296 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- EIF3J | c.317A>C p.K106T | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- FANCM | c.670G>C p.A224P | Missense Mutation (SNP) | VAF 85/256 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXO21 | c.1436T>C p.I479T (on ENST00000330622 / NM_033624.3; = p.I472T on NM_015002.3) | Missense Mutation (SNP) | VAF 74/258 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, varscan2
- FLI1 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- FNDC3B | c.568C>A p.P190T | Missense Mutation (SNP) | VAF 117/337 reads (35%) | SIFT tolerated (0.8); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GPR25 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- IDO1 | c.281A>C p.K94T | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2
- IL5RA | c.13G>C p.A5P | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- MAST3 | c.1332G>A p.M444I | Missense Mutation (SNP) | VAF 99/385 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- MDN1 | c.10340C>T p.P3447L | Missense Mutation (SNP) | VAF 70/231 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLEKHM2 | c.397C>A p.H133N | Missense Mutation (SNP) | VAF 64/237 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- POP7 | c.137A>C p.K46T | Missense Mutation (SNP) | VAF 179/559 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- SHROOM3 | c.3389G>C p.G1130A | Missense Mutation (SNP) | VAF 92/374 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.006); called by muse, varscan2
- STAMBP | c.384del p.A129Qfs*21 | Frame Shift Del (DEL) | VAF 34/108 reads (31%) | called by mutect2, pindel
- TSPYL6 | c.115_118del p.M39Lfs*51 | Frame Shift Del (DEL) | VAF 87/362 reads (24%) | called by mutect2, pindel, varscan2
- ZFP3 | c.923del p.P308Hfs*239 | Frame Shift Del (DEL) | VAF 73/238 reads (31%) | called by mutect2, pindel, varscan2
- ZNF77 | c.729A>C p.K243N | Missense Mutation (SNP) | VAF 71/246 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ABHD6 | c.246C>T p.A82= | Silent (SNP) | VAF 112/246 reads (46%) | called by muse, mutect2, varscan2
- AMELY | c.246C>T p.P82= (on ENST00000383036 / NM_001364814.1; = p.P68= on NM_001143.1) | Silent (SNP) | VAF 18/283 reads (6%) | catalogued as rs753555850, COSV53095832; called by muse, mutect2
- CHRNB2 | c.996G>A p.A332= | Silent (SNP) | VAF 134/427 reads (31%) | catalogued as rs762184252; called by muse, mutect2, varscan2
- CLEC10A | c.558G>A p.V186= (on ENST00000254868 / NM_182906.4; = p.V162= on NM_006344.4) | Silent (SNP) | VAF 21/136 reads (15%) | catalogued as rs1253727725; called by muse, mutect2, varscan2
- CSAD | c.87G>A p.V29= (on ENST00000444623 / NM_001244705.2; = p.V56= on NM_015989.5) | Silent (SNP) | VAF 77/290 reads (27%) | catalogued as rs766657444; called by muse, mutect2, varscan2
- PDK4 | c.465T>C p.L155= | Silent (SNP) | VAF 17/73 reads (23%) | called by muse, mutect2, varscan2
- SHROOM3 | c.3390C>T p.G1130= | Silent (SNP) | VAF 92/378 reads (24%) | called by muse, varscan2
- TRPV5 | c.573C>T p.A191= | Silent (SNP) | VAF 99/296 reads (33%) | catalogued as rs374962671; called by muse, varscan2
- AC092329.3 | c.-211-607T>A | Intron (SNP) | VAF 114/340 reads (34%) | called by muse, mutect2, varscan2
- ARHGEF16 | c.589-70G>C | Intron (SNP) | VAF 39/137 reads (28%) | catalogued as rs1191680314; called by muse, mutect2, varscan2
- CROCC | c.1808+742T>C | Intron (SNP) | VAF 10/58 reads (17%) | called by muse, mutect2, varscan2
- GBA3 | c.58+21020T>A | Intron (SNP) | VAF 31/126 reads (25%) | catalogued as rs1341974558; called by muse, mutect2, varscan2
- GVINP1 | n.3146C>T | RNA (SNP) | VAF 73/299 reads (24%) | catalogued as rs1010274670; called by muse, mutect2, varscan2
- KRBA1 | c.466+176G>A | Intron (SNP) | VAF 119/393 reads (30%) | called by muse, mutect2, varscan2
- ODF4 | c.*1T>G | 3'UTR (SNP) | VAF 30/108 reads (28%) | called by muse, mutect2
- PAH | c.*5A>G | 3'UTR (SNP) | VAF 116/348 reads (33%) | called by muse, mutect2, varscan2
- PRICKLE4 | c.668-10C>T | Intron (SNP) | VAF 28/131 reads (21%) | called by muse, mutect2, varscan2
- RAB40C | chr16:630038 C>G | 3'Flank (SNP) | VAF 131/397 reads (33%) | called by muse, mutect2, varscan2
- SLC22A10 | n.1002G>A | RNA (SNP) | VAF 27/112 reads (24%) | called by muse, mutect2, varscan2
- THAP9 | c.731+2787del | Intron (DEL) | VAF 77/297 reads (26%) | called by mutect2, pindel, varscan2
